Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PK, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PK-01A (Primary Tumor).

ICD O-3
Adenocarcinoma, intestinal
Type 8144/3
Site: Gastroesophageal junction
C16.0
JW 3/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

1 - "Hepatogastric ligament":
Absence of neoplasia.

2 - "Greater omentum":
Absence of neoplasia.

3 - "Product of standardized esophagogastrectomy":
- Moderately differentiated adenocarcinoma (intestinal type of Lauren's classification),
infiltrating the serosa;
- Maximum size of the tumor: 8.0 cm;
- Angiolymphatic invasion: present
- Perineural invasion: not detected;
- Surgical margins: absence of neoplasia.
- D2 lymphadenectomy:
Right paracardics: involved by neoplasia (1/6).
Left paracardics: involved by neoplasia (3/7).
Lesser curvature: involved by neoplasia (2/3).
Short gastric vessels: adipose tissue uninvolved by neoplasia.
Suprapyloric: adipose tissue uninvolved by neoplasia.
Left gastric artery: involved by neoplasia (1/7).
Anterior hepatic artery: involved by neoplasia (1/2).
Celiac trunk: involved by neoplasia (2/5).
Inferior paraesophageal: involved by neoplasia (1/2).

4 - "Esophageal margin":
Absence of neoplasia.

5 - "Liver Biopsy":
Mild steatosis.
Absence of neoplasia.

HBGA Discrepancy		✓

Source: NCI Genomic Data Commons file 0ca579b9-8f64-4637-945a-9d3e36471b7d (TCGA-VQ-A8PK.2619F062-6E2D-4412-95C3-B104C86EDBFC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).